CCDI case PBCPBA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3aa2ab7d-8387-4c2a-842b-3a1353b75aaf

Demographics
Sex at birth: male.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 22.5 years (8,200 days).

Biospecimens (3 samples)
- Sample 0DX0Q2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX0QC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX0QX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
